Surgical pathology report (de-identified scan), TCGA case TCGA-42-2588, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-42-2588-01A (Primary Tumor).

[page 1 of 2]
- [REDACTED]
- A. Omentum, excision
- B. Terminal ileum, cecum, appendix and omentum

CLINICAL NOTES

CLINICAL NOTES: Ovarian cancer.

GROSS DESCRIPTION

- A. The specimen is received fresh labeled "omentum" and consists of a 17 x 9 x 1.5 cm firm rubbery piece of tan to pink tissue consistent with omental cake. No normal omental fat is present. Representative tissue is submitted fresh for tissue procurement. Additional sections are submitted for permanent sections. RS-4. The cut section has a yellow to tan firm rubbery cut section. [REDACTED]
- B. Received fresh, subsequently fixed in formalin, labeled "terminal ileum, cecum, appendix and omentum" is a right colon and portion of omentum. The omentum is 9.5 x 3.5 x 2 cm and is red-yellow-white, firm and rubbery. The specimen is sectioned to show a yellow lobular cut surface with possible tumor present. Tumor makes up approximately 40% of the specimen grossly. Also grossly identified in the specimen container is a right colon. The specimen shows a portion of small bowel which is 30 cm. The proximal margin is stapled and inked. The colon, itself, is 9.5 cm and the distal aspect is stapled and inked. The serosa of the specimen is pink-red, dusky, firm, partially covered with tumor nodules throughout. Appendix is grossly identified adherent to the fat measuring 5 x 0.3 cm and also is studded with tumor nodules. Mucosa of the specimen is opened to show pink-tan smooth glistening mucosa with an average circumference of 4 cm in the small bowel and 9 cm in the cecum and colon. No tumor nodules are grossly identified in the mucosa of the specimen. Possible lymph nodes are grossly identified, some of which may be possibly positive.

GROSS DESCRIPTION

Representative sections of the specimen are submitted as follows:
Blocks 1, 2 - representative section of omentum; block 3 - representative luminal margin and ileocecal valve specimen; block 4 - representative section appendix proximal end inked; blocks 5, 6 - representative section of the specimen with tumor present on the surface; blocks 7-10 - representative sections possible lymph node.

[REDACTED]

[page 2 of 2]
MICROSCOPIC DESCRIPTION

A. Microscopic examination of the omentum reveals extensive

poorly differentiated serous carcinoma, FIGO grade 3. Much

lymphatic space invasion is present.

B. Microscopic examination of the terminal ileum, cecum, appendix and omentum reveals much additional FIGO grade 3 serous adenocarcinoma. Tumor is present throughout the omentum with

lymphatic space invasion. Tumor is present throughout the serosal surface of the large intestine and small intestine and appendix and present in 8 of 9 pericolic lymph nodes with extranodal tumor. Tumor extends into the muscular wall of the intestines. No definite

infiltration through the wall into the mucosa is identified.

NOTE: For ovarian or primary peritoneal carcinoma, this tumor is at

least pT3b (FIGO IIIb). Clinical correlation is recommended in regard to any further distant metastases that have not been sampled at the time of this procedure.

DIAGNOSIS

A. Omentum, excision:

Metastatic poorly differentiated serous carcinoma, FIGO grade 3

DIAGNOSIS

with prominent lymphatic space invasion.

B. Terminal ileum, cecum, appendix and omentum, resection:

Serous carcinoma poorly differentiated, FIGO grade 3 extensively involving serosa of appendix and small and large intestine with focal extension into muscular wall.

Metastatic tumor present throughout the omentum and within 8 of 9 pericolic lymph nodes.

Source: NCI Genomic Data Commons file 1e32f8ab-aed3-4667-950d-3a245446d661 (TCGA-42-2588.0A11A32D-BC41-4322-BC00-357ECDD593AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).